Gene-level copy-number profile of tumor specimen BLGSP-71-32-00695-01A from CGCI case BLGSP-71-32-00695, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 64.9 years (23,702 days).
Specimen BLGSP-71-32-00695-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ecf3f1d7-3e7a-448b-8015-03e96cf8b9cf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-32-00695-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,406 have no estimate.
https://portal.gdc.cancer.gov/files/139d6507-b4a5-442b-adc5-4985a69d1f0e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 599; copy number 2: 55,857; copy number 3: 1,644; copy number 4: 100; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,811,359–143,825,837, 1 gene: AC239798.1.
- chr2:88,861,886–89,027,731, 13 genes (within-gene range 0–2): IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11.
- chr2:89,078,010–89,085,787, 2 genes (within-gene range 0–1): IGKV2-14, IGKV3-15.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:89,195,761–89,201,651, 1 gene, copy number 5: SLC22A31.

Autosomal genes at a single copy (total copy number 1): 594. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
